CCDI case PBBWLY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/18becc92-da21-4690-8d2e-e8bcea6d3019

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 15.7 years (5,744 days).

Biospecimens (3 samples)
- Sample 0DJBLQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJC33: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJC3A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
